FM case AD6177 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Uterus, NOS.
https://portal.gdc.cancer.gov/cases/406544be-5538-4662-a65a-c5d16ef15871

Female, 56.3 years: Clear cell adenocarcinoma, NOS (ICD-O-3 8310/3) of the uterus; metastasis biopsied or resected from the endometrium. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Metastatic.
